Gene-level copy-number profile of tumor specimen TCGA-26-5135-01A from TCGA case TCGA-26-5135, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.5 years (26,490 days).
Specimen TCGA-26-5135-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.71adf2bb-a1ae-4675-8f6f-71db8bf322ff.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-26-5135-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93997cdc-c7d7-40d3-8282-b877e2991a81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 556; copy number 1: 2,568; copy number 2: 53,809; copy number 3: 3,103; copy number 5: 106; copy number 10: 5; copy number 15: 5; copy number 17: 6; copy number 18: 1; copy number 22: 8; copy number 23: 1; copy number 24: 1; copy number 25: 43; copy number 28: 34; copy number 29: 4; copy number 31: 4; copy number 32: 18; copy number 34: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-26-5135-01A-01D-1479-01): tumor purity 0.81, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:66,596,361–67,169,595, 1 gene (within-gene range 0–1): MAST4.
- chr5:67,001,383–69,069,200, 31 genes: MAST4-AS1, CD180, AC010420.1, AC008459.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2, AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2, AC010280.1, AC010280.3, AC093523.1, VWA8P1, U8, AC093248.1, RN7SKP251, LINC02198, AC010273.3, SUMO2P4.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr17:41,265,339–41,271,835, 2 genes: KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 237 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–52,692,999, 14 genes, copy number 25: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3.
- chr4:53,899,871–55,395,847, 33 genes, copy number 10–28 (within-gene range 1–28): AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1.
- chr4:55,798,636–56,033,361, 7 genes, copy number 22: RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135.
- chr4:56,097,390–56,097,504, 1 gene, copy number 22: RNA5SP161.
- chr12:57,723,761–58,098,013, 26 genes, copy number 25 (within-gene range 2–25): AGAP2, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1.
- chr12:59,322,765–59,586,943, 6 genes, copy number 32 (within-gene range 1–32): AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P.
- chr12:60,092,864–60,096,071, 1 gene, copy number 18: AC080011.1.
- chr12:61,231,159–61,702,771, 3 genes, copy number 29–34: AC090017.1, DUX4L52, AC090629.1.
- chr12:61,775,923–61,880,772, 2 genes, copy number 29: RPL21P104, KRT8P19.
- chr12:63,822,021–64,162,217, 10 genes, copy number 28: PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1.
- chr12:67,443,105–67,590,771, 1 gene, copy number 23 (within-gene range 2–25): LINC02408.
- chr12:68,332,888–68,451,663, 1 gene, copy number 24 (within-gene range 2–53): LINC02384.
- chr12:68,426,331–68,576,136, 5 genes, copy number 28: AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP.
- chr12:68,626,870–68,627,375, 2 genes, copy number 28: RPL10P12, SNORA70G.
- chr12:68,746,125–68,971,570, 10 genes, copy number 32: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,643,360–69,699,476, 2 genes, copy number 32 (within-gene range 1–32): BEST3, AC025263.3.
- chr12:69,738,860–69,959,097, 3 genes, copy number 31 (within-gene range 1–31): RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 31: AC078922.1.
- chr12:70,515,870–70,637,440, 2 genes, copy number 25: PTPRB, AC083809.1.
- chr12:70,671,918–70,672,856, 1 gene, copy number 25: FAHD2P1.
- chr14:105,764,503–106,377,733, 106 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,568. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
